Somatic mutation profile of cancer-model specimen HCM-CSHL-0434-C24-85A (3D Organoid; aliquot HCM-CSHL-0434-C24-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15c24009-f04c-4d9f-9366-327da8c76e1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0434-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0434-C24-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef289231-4346-4fa6-b38d-858eee4310df

The open-access MAF lists 109 somatic variants for this specimen: 64 protein-altering or splice-affecting, 27 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 27, Intron 7, 5'UTR 4, Nonsense Mutation 3, Splice Site 2, 5'Flank 2, RNA 2, 3'UTR 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 225/316 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 415/416 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARL15 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1372323929; called by muse, mutect2
- ASCC3 | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 156/280 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs187359221; called by muse, mutect2, varscan2
- CAPRIN1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1324425337; called by muse, mutect2, varscan2
- CASS4 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.591); catalogued as rs144420438; called by muse, mutect2, varscan2
- CFAP46 | c.7202G>A p.R2401Q | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375364632, COSV99583945; called by muse, mutect2, varscan2
- CFL1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57380536; called by muse, mutect2, varscan2
- CHAF1A | c.1387G>C p.G463R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56673422; called by muse, mutect2
- CHST15 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757439959, COSV60562927; called by muse, mutect2, varscan2
- DNAH7 | c.8779C>T p.Q2927* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs374570869; called by muse, mutect2, varscan2
- DUSP7 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 226/228 reads (99%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs879043778; called by muse, mutect2, varscan2
- ESX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 123/125 reads (98%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs782576955; called by muse, mutect2, varscan2
- FARP2 | c.288+2T>C p.X96_splice | Splice Site (SNP) | VAF 72/144 reads (50%) | catalogued as rs1166151853; called by muse, mutect2, varscan2
- FLG | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 144/636 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1341902735; called by muse, mutect2, varscan2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 69/70 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2, varscan2
- GMCL2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1368534206; called by mutect2, varscan2
- GRIA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs531706550, COSV53596718; called by muse, mutect2, varscan2
- HGS | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 94/580 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs752721915; called by muse, mutect2, varscan2
- KLHL42 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 362/500 reads (72%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as rs374664683; called by muse, mutect2, varscan2
- LGALS2 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50758391; called by muse, mutect2, varscan2
- LRRTM4 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1479336871, COSV69140756; called by muse, mutect2, varscan2
- LTBP1 | c.2878G>T p.E960* (on ENST00000404816 / NM_206943.4; = p.E634* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 158/158 reads (100%) | catalogued as COSV100617209, COSV63195429; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770408937, COSV66775187; called by muse, mutect2, varscan2
- MPDZ | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 108/108 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs779501527; called by muse, mutect2, varscan2
- MYO3A | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV56320262; called by muse, mutect2, varscan2
- NMUR2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs764432864, COSV54918182; called by muse, mutect2, varscan2
- OR2AJ1 | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100561459; called by muse, mutect2
- PLXNA2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs778037020; called by muse, mutect2, varscan2
- PPIA | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs767375293, COSV63534169; called by muse, mutect2, varscan2
- SIPA1L2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 100/138 reads (72%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs368264412; called by muse, mutect2, varscan2
- SKOR1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58244084; called by muse, mutect2, varscan2
- SLC22A11 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 121/554 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.137); catalogued as COSV57252925; called by muse, mutect2, varscan2
- SLC24A3 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 249/517 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as COSV100043446; called by muse, mutect2, varscan2
- TMPRSS6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 196/459 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1270960721, COSV60976662; called by muse, mutect2, varscan2
- TUB | c.124C>T p.R42C (on ENST00000299506 / NM_177972.3; = p.R97C on NM_003320.4) | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772509519; called by muse, mutect2, varscan2
- TUBA3C | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs372020555, COSV67139306; called by muse, mutect2, varscan2
- VPS13D | c.8530G>T p.D2844Y | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1425394183; called by muse, mutect2, varscan2
- XPO6 | c.2612G>A p.R871K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs780775153; called by muse, mutect2, varscan2
- ZBBX | c.1708del p.T570Lfs*11 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | catalogued as COSV56796702; called by mutect2, pindel, varscan2
- ZBED9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as rs185476387, COSV71729796; called by muse, mutect2, varscan2
- ZNF208 | c.3816G>C p.K1272N | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV68103774; called by muse, mutect2
- ARID3C | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CD48 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2
- COL15A1 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A1 | c.4870dup p.Y1624Lfs*83 | Frame Shift Ins (INS) | VAF 101/650 reads (16%) | called by mutect2, pindel, varscan2
- CWC22 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- DACT1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 209/294 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GON4L | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 272/366 reads (74%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.2938G>C p.V980L | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LUZP1 | c.2873C>A p.T958K | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- MBD2 | c.477G>A p.W159* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- NPAS2 | c.58_60del p.K20del | In Frame Del (DEL) | VAF 26/90 reads (29%) | called by pindel, varscan2
- PPHLN1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPHLN1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PRPF6 | c.2029-1G>A p.X677_splice | Splice Site (SNP) | VAF 189/448 reads (42%) | called by muse, mutect2, varscan2
- PZP | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLC43A1 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.012); called by muse, mutect2
- TMEM8B | c.1102C>A p.R368S | Missense Mutation (SNP) | VAF 56/57 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBR5 | c.5366G>A p.S1789N | Missense Mutation (SNP) | VAF 194/385 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- VCAN | c.8771A>C p.E2924A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- WFDC1 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 193/290 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF26 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSWIM5 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- A2M | c.66C>T p.D22= | Silent (SNP) | VAF 80/318 reads (25%) | catalogued as rs1397674410; called by muse, mutect2, varscan2
- AJAP1 | c.717C>T p.S239= | Silent (SNP) | VAF 38/38 reads (100%) | catalogued as rs377710853; called by muse, mutect2, varscan2
- ANKRD44 | c.498C>T p.I166= | Silent (SNP) | VAF 52/319 reads (16%) | catalogued as rs541978099, COSV56549343, COSV99985843; called by muse, mutect2, varscan2
- ARMC4 | c.1668C>T p.A556= | Silent (SNP) | VAF 102/413 reads (25%) | catalogued as rs761407359; called by muse, mutect2, varscan2
- CD36 | c.240C>T p.S80= | Silent (SNP) | VAF 66/304 reads (22%) | catalogued as rs776269710; called by muse, mutect2, varscan2
- CDH2 | c.438A>G p.Q146= | Silent (SNP) | VAF 57/72 reads (79%) | called by muse, mutect2, varscan2
- CLUH | c.3828C>T p.A1276= (on ENST00000435359; = p.A1315= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs778665976, COSV70928918; called by muse, mutect2, varscan2
- DLGAP2 | c.933G>A p.T311= | Silent (SNP) | VAF 152/358 reads (42%) | catalogued as rs746806848; called by muse, mutect2, varscan2
- DYRK1A | c.255C>T p.F85= | Silent (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- FAM53C | c.222G>C p.L74= | Silent (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- FBXO28 | c.858C>T p.R286= | Silent (SNP) | VAF 195/285 reads (68%) | called by muse, mutect2, varscan2
- HAMP | c.210C>T p.C70= | Silent (SNP) | VAF 184/2068 reads (9%) | catalogued as rs760104316, COSV55885844; called by muse, mutect2
- HECA | c.1620C>T p.L540= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs1380380608, COSV62768603; called by muse, mutect2
- HOXB3 | c.127C>T p.L43= | Silent (SNP) | VAF 198/377 reads (53%) | called by muse, mutect2, varscan2
- HSPG2 | c.7662C>T p.N2554= | Silent (SNP) | VAF 346/347 reads (100%) | called by muse, mutect2, varscan2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 140/324 reads (43%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2, varscan2
- OCA2 | c.1221C>T p.F407= | Silent (SNP) | VAF 123/209 reads (59%) | catalogued as rs370349105; called by muse, mutect2, varscan2
- OR5C1 | c.732C>T p.T244= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs532966704, COSV101030530; called by muse, mutect2, varscan2
- ORAI2 | c.489C>T p.A163= | Silent (SNP) | VAF 220/759 reads (29%) | catalogued as rs769632596; called by muse, mutect2, varscan2
- PCDHGA7 | c.1545C>T p.Y515= | Silent (SNP) | VAF 13/216 reads (6%) | catalogued as rs751427123, COSV53930622; called by muse, mutect2
- SHANK1 | c.6015C>T p.P2005= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs753950279, COSV53251529; called by muse, mutect2, varscan2
- SLC26A4 | c.474C>T p.D158= | Silent (SNP) | VAF 554/745 reads (74%) | catalogued as COSV55915305; called by muse, mutect2, varscan2
- SLC6A18 | c.1257C>T p.F419= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as rs757382342, COSV57250970; called by mutect2, varscan2
- SLC9A9 | c.1404C>T p.L468= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs576013614, COSV100339003, COSV57235318; called by muse, mutect2, varscan2
- TP73 | c.1863C>T p.A621= | Silent (SNP) | VAF 181/181 reads (100%) | called by muse, mutect2, varscan2
- TUSC1 | c.402A>G p.E134= | Silent (SNP) | VAF 143/370 reads (39%) | called by muse, mutect2, varscan2
- ZNF862 | c.58T>C p.L20= | Silent (SNP) | VAF 93/94 reads (99%) | called by muse, mutect2, varscan2
- C16orf87 | c.-3A>G | 5'UTR (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29699652 T>C | 3'Flank (SNP) | VAF 217/821 reads (26%) | called by muse, mutect2, varscan2
- CANX | chr5:179698531 T>C | 5'Flank (SNP) | VAF 87/343 reads (25%) | called by muse, mutect2, varscan2
- CFAP221 | c.2318+1423C>T | Intron (SNP) | VAF 12/21 reads (57%) | catalogued as rs548777396, COSV99733393; called by muse, mutect2, varscan2
- CLOCK | c.1206+26T>A | Intron (SNP) | VAF 34/98 reads (35%) | catalogued as rs1431906788; called by muse, varscan2
- EMP1 | c.*1781C>A | 3'UTR (SNP) | VAF 52/211 reads (25%) | called by muse, mutect2, varscan2
- FMN2 | c.-187C>T | 5'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- GPM6A | c.37+24852G>A | Intron (SNP) | VAF 11/148 reads (7%) | catalogued as rs942257620; called by muse, mutect2
- HNRNPA1L2 | c.-1C>A | 5'UTR (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2
- LINC01164 | n.673_675delinsCCA | RNA (TNP) | VAF 18/89 reads (20%) | called by muse*, mutect2*, pindel, varscan2*
- MCF2L2 | c.77-10749del | Intron (DEL) | VAF 54/143 reads (38%) | called by mutect2, pindel, varscan2
- MTHFD2L | chr4:74157926 T>C | 5'Flank (SNP) | VAF 157/172 reads (91%) | catalogued as rs1299716458; called by muse, mutect2, varscan2
- REPIN1 | c.-92C>G | 5'UTR (SNP) | VAF 152/152 reads (100%) | catalogued as rs1367020694; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6637C>T | RNA (SNP) | VAF 7/162 reads (4%) | catalogued as rs940726834; called by muse, mutect2
- SLC26A3 | c.1677+28dup | Intron (INS) | VAF 399/590 reads (68%) | catalogued as rs771040356; called by mutect2, pindel*, varscan2
- SLC39A9 | c.*3077C>T | 3'UTR (SNP) | VAF 49/49 reads (100%) | called by muse, mutect2, varscan2
- TGFBI | c.459+22C>T | Intron (SNP) | VAF 38/51 reads (75%) | catalogued as rs749930646; called by muse, mutect2, varscan2
- ZEB1 | c.58+43931G>A | Intron (SNP) | VAF 307/486 reads (63%) | catalogued as rs3895218; called by muse, mutect2, varscan2
